Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A7J0, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A7J0-01A (Primary Tumor).

ICD-O-3
Oligodendroglioma
grade III 9451/3
Site Brain, supratentorial
NOS C71.0
JH 9/30/13

anaplastic glioma with honeycomb pattern
IDH1 R132S mutation present
1p/19q wild type

Diagnosis: anaplastic oligodendroglioma WHO grade III

untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 6ce662da-81f9-431c-a5d6-2bb235105bc8 (TCGA-S9-A7J0.B1D1504E-B9FB-4974-A8B6-24B6A86C780B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).